Somatic mutation profile of tumor specimen TARGET-10-PAPHHP-09A (aliquot TARGET-10-PAPHHP-09A-01D) from TARGET case TARGET-10-PAPHHP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.5 years (2,013 days).
Specimen TARGET-10-PAPHHP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23a0199a-4c92-4137-8889-a7a6b4ec97e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPHHP-10A (Blood Derived Normal), aliquot TARGET-10-PAPHHP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8a43d29-0ad3-43d3-bbf1-92c81bc36cc5

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, Frame Shift Ins 1, Intron 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.6110+2T>A p.X2037_splice | Splice Site (SNP) | VAF 27/58 reads (47%) | catalogued as COSV64877350; called by muse, mutect2, varscan2
- FLT3 | c.1727T>C p.L576P | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV54047457, COSV54049031, COSV54049919; called by muse, mutect2, varscan2
- HID1 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV59351317; called by mutect2, varscan2
- NPNT | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs768930607, COSV59752102; called by muse, mutect2, varscan2
- RIBC2 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs559429477; called by muse, mutect2, varscan2
- SEMA5A | c.1678G>A p.V560M | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.232); catalogued as rs200629661, COSV101227086; called by muse, mutect2, varscan2
- MUC5B | c.4624C>T p.Q1542* | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | called by muse, mutect2, varscan2
- NIPBL | c.4424_4425insCCCC p.L1475Ffs*5 | Frame Shift Ins (INS) | VAF 5/22 reads (23%) | called by mutect2, pindel*
- TLL1 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IRX6 | c.27G>A p.P9= | Silent (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2, varscan2
- RCAN1 | c.481C>T p.L161= | Silent (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- NRG1 | c.502+30931G>A | Intron (SNP) | VAF 15/34 reads (44%) | catalogued as rs750558927, COSV99827170, COSV99829337; called by muse, mutect2, varscan2
